Somatic mutation profile of tumor specimen TCGA-B1-A47N-01A (aliquot TCGA-B1-A47N-01A-11D-A25F-10) from TCGA case TCGA-B1-A47N, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-B1-A47N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56d14fba-ca3e-4789-adb8-00e212610fd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A47N-10A (Blood Derived Normal), aliquot TCGA-B1-A47N-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9106f67-ea94-4190-a048-26eb055100a7

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, 3'UTR 2, 5'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.5824G>A p.V1942M | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1367042445, COSV57203671; called by muse, mutect2
- ASIC5 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV72232505; called by muse, mutect2, varscan2
- DOCK7 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51995895; called by muse, mutect2, varscan2
- LAMC3 | c.3494G>A p.S1165N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs1453568158, COSV63088589; called by muse, mutect2, varscan2
- LPA | c.2821T>C p.Y941H | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV60296776; called by muse, mutect2, varscan2
- MUC4 | c.14002C>T p.R4668W (on ENST00000463781 / NM_018406.7; = p.R432W on NM_004532.6) | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs748713367, COSV57765525; called by muse, mutect2
- MYBBP1A | c.3079C>A p.R1027S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs200492249, COSV54593234, COSV99627321; called by muse, mutect2, varscan2
- PC | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV63079030; called by muse, mutect2, varscan2
- PGAP1 | c.1225C>A p.Q409K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV61323831; called by muse, mutect2
- PLEKHO1 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV50309760, COSV99215209; called by muse, mutect2, varscan2
- PROSER1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61486157; called by muse, mutect2
- SLC6A12 | c.1100T>C p.F367S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62883878; called by muse, mutect2, varscan2
- STPG4 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV54277849; called by muse, mutect2, varscan2
- SYNGAP1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV53378287; called by muse, mutect2, varscan2
- TAX1BP1 | c.1987A>T p.R663* | Nonsense Mutation (SNP) | VAF 43/71 reads (61%) | catalogued as COSV55290514; called by muse, mutect2, varscan2
- TPRG1 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV61463377; called by muse, mutect2, varscan2
- WDR81 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as rs1253960046, COSV58478517; called by muse, mutect2, varscan2
- ZNF2 | c.973C>G p.P325A (on ENST00000611147 / NM_001291605.2; = p.P312A on NM_021088.4) | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs779824720, COSV54636105, COSV54638353; called by muse, mutect2, varscan2
- ZNF880 | c.140-1G>A p.X47_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV59813200; called by muse, mutect2
- HOXD8 | c.699_708dup p.T237Pfs*107 | Frame Shift Ins (INS) | VAF 25/58 reads (43%) | called by mutect2, varscan2
- KNTC1 | c.3714del p.C1239Afs*14 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ARHGAP21 | c.5415A>G p.G1805= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV57602100; called by muse, mutect2, varscan2
- GALNT9 | c.867C>T p.N289= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs554022886, COSV61095893; called by muse, mutect2, varscan2
- GPR12 | c.984G>A p.A328= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs754587158, COSV67344029; called by muse, mutect2, varscan2
- HAGHL | c.639G>C p.G213= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV52400733; called by muse, mutect2, varscan2
- OTOG | c.735G>A p.Q245= | Silent (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- PLCB2 | c.1593G>A p.S531= | Silent (SNP) | VAF 99/225 reads (44%) | catalogued as rs181950993; called by muse, mutect2, varscan2
- TSPYL2 | c.993C>A p.R331= | Silent (SNP) | VAF 51/56 reads (91%) | catalogued as COSV60233557; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407725 del C | 5'Flank (DEL) | VAF 50/201 reads (25%) | called by pindel, varscan2
- OR52A1 | c.-112C>A | 5'UTR (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- RRAGA | c.*376T>A | 3'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100998097; called by muse, mutect2
- WWC2 | c.*4639A>C | 3'UTR (SNP) | VAF 49/99 reads (49%) | catalogued as COSV100032833; called by muse, mutect2, varscan2
